Surgical pathology report (de-identified scan), TCGA case TCGA-16-1047, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Toronto Western Hospital, specimen TCGA-16-1047-01B (Primary Tumor).

Patient Name: [REDACTED]

MRN: [REDACTED]
DOB: [REDACTED] (Age:)

Gender: F

Ordering MD: [REDACTED]

Service: [REDACTED]
Visit #: [REDACTED]
Location: [REDACTED]
Facility: [REDACTED]

Collected:
Resulted:

Surgical Pathology Consultation Report

SPECIMEN(S) RECEIVED

1. BRN: RIGHT FRONTAL PARIETAL TEMPORAL LESION

DIAGNOSIS

Brain, right frontal parietal temporal region: Glioblastoma (WHO grade IV)

ELECTRONICALLY VERIFIED BY:

CLINICAL HISTORY RIGHT BRAIN TUMOUR

GROSS DESCRIPTION

The specimen container, labeled with the patient's name and as "right frontal parietal temporal lesion", contains a piece of pinkish white tissue, received in 10% buffered formalin. In aggregate this measures 0.6 x 0.5 x 0.3 cm and weighs less than 1 gm. 1A - specimen submitted in toto.

MICROSCOPIC DESCRIPTION

Sections show an infiltrating glial tumour of predominantly astrocytic derivation. Numerous mitotic figures are present. There is abundant microvascular proliferation. Areas of necrosis are not present in the specimen.

Source: NCI Genomic Data Commons file 0258ee52-9aec-40cf-b70a-8405e00c0452 (TCGA-16-1047.E45EE1FB-3821-4F46-A033-8A292A5B0884.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).